Somatic mutation profile of tumor specimen TCGA-98-8020-01A (aliquot TCGA-98-8020-01A-11D-2244-08) from TCGA case TCGA-98-8020, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 56.2 years (20,509 days).
Specimen TCGA-98-8020-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b92dc07f-16a6-4018-9bd4-874fc3b8a39e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-98-8020-10A (Blood Derived Normal), aliquot TCGA-98-8020-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8405e05-2305-4a40-91db-1ffb4e415117

The open-access MAF lists 103 somatic variants for this specimen: 79 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 21, Nonsense Mutation 1, 3'UTR 1, Splice Site 1, Splice Region 1, Frame Shift Del 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA4 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as rs368489876, CD031840, CM086820; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TFAP2A | c.766C>G p.R256G (on ENST00000482890; = p.R248G on NM_001032280.3) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs151344528, CM085952, CM110093, COSV100116513; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 27/93 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 31/94 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACLY | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV61250134; called by muse, mutect2, varscan2
- ACLY | c.1564G>C p.D522H | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV100709498; called by muse, mutect2, varscan2
- ADGRB3 | c.391C>G p.R131G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV100999635; called by muse, mutect2
- AL031777.2 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV100587264, COSV61912013, COSV61912148; called by muse, mutect2, varscan2
- ANO2 | c.2248G>A p.G750S (on ENST00000356134 / NM_001278597.3; = p.G754S on NM_001278596.3) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100499626; called by muse, mutect2, varscan2
- ATP6V1A | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99849790; called by muse, mutect2, varscan2
- B3GNT3 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs1374268623, COSV59438570; called by muse, mutect2, varscan2
- CACNA1E | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 67/293 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV62439247; called by muse, mutect2, varscan2
- CDCP1 | c.2449A>T p.S817C | Missense Mutation (SNP) | VAF 121/178 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.54); catalogued as COSV99943817, COSV99944449; called by muse, mutect2, varscan2
- CDH10 | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV52577588, COSV52600832; called by muse, mutect2, varscan2
- CFAP92 | c.237C>G p.I79M | Missense Mutation (SNP) | VAF 31/290 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99414567; called by muse, mutect2, varscan2
- CLEC5A | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101407741; called by muse, mutect2, varscan2
- CNTNAP5 | c.2494C>A p.L832I | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV101442995; called by muse, mutect2, varscan2
- COL17A1 | c.1509G>C p.E503D | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV100793019; called by muse, mutect2, varscan2
- COL1A1 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs756087773, COSV99866294; called by muse, mutect2, varscan2
- CPSF6 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV99878959; called by muse, mutect2, varscan2
- CSMD3 | c.4784C>T p.S1595F (on ENST00000297405 / NM_001363185.1; = p.S1491F on NM_052900.3) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs989741793, COSV52253830, COSV52270600; called by muse, mutect2
- CTAGE1 | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV101194420; called by muse, mutect2, varscan2
- CTAGE1 | c.795G>T p.M265I | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV101194421; called by muse, mutect2, varscan2
- DMD | c.10465C>T p.R3489C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771240938, COSV100625868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK7 | c.5064G>C p.L1688F (on ENST00000635253 / NM_001367561.1; = p.L1657F on NM_033407.3) | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52005309, COSV52018060; called by muse, mutect2, varscan2
- DYNC2I1 | c.1152C>A p.D384E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as COSV101337599; called by muse, mutect2, varscan2
- ERICH3 | c.4250C>A p.A1417E | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV100443269; called by muse, varscan2
- ERMP1 | c.1175C>G p.S392C | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); catalogued as COSV99284397; called by muse, mutect2, varscan2
- FLG | c.2310C>G p.H770Q | Missense Mutation (SNP) | VAF 230/575 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100910442; called by muse, mutect2, varscan2
- GEN1 | c.2221G>C p.D741H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV100437733; called by muse, mutect2, varscan2
- H2AC13 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100704308; called by muse, mutect2, varscan2
- H2AC8 | c.181G>C p.A61P | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55126172; called by muse, mutect2, varscan2
- HERC2 | c.3953C>T p.S1318L | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.366); catalogued as rs147535565; called by muse, mutect2, varscan2
- HK3 | c.2677G>C p.V893L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV99457751; called by muse, mutect2, varscan2
- IGHG4 | c.932C>G p.A311G | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs781110538; called by muse, mutect2, varscan2
- JARID2 | c.3146G>T p.R1049L | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.136); catalogued as COSV59187763, COSV59194965; called by muse, mutect2, varscan2
- KLHDC7B | c.1450C>T p.R484C (on ENST00000395676; = p.R1125C on NM_138433.5) | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773683142, COSV67465165; called by muse, mutect2, varscan2
- KRT19 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as COSV99562824; called by muse, varscan2
- MACF1 | c.12197G>C p.R4066P (on ENST00000372915; = p.R1999P on NM_012090.5) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as COSV99240915; called by mutect2, varscan2
- MADD | c.2227C>T p.P743S | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100210953; called by muse, mutect2, varscan2
- MKI67 | c.7294G>C p.E2432Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.114); catalogued as COSV100896115; called by muse, mutect2, varscan2
- MLH3 | c.2599G>C p.E867Q | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV53152202; called by muse, mutect2, varscan2
- MSI1 | c.789A>C p.T263= | Splice Region (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99981356; called by muse, mutect2, varscan2
- MYH9 | c.1813G>C p.D605H | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99337774; called by muse, varscan2
- NBEA | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100076432; called by muse, mutect2, varscan2
- NEDD4 | c.35G>C p.R12T | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV100163250; called by muse, mutect2, varscan2
- NEFH | c.1194G>C p.E398D | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100151206, COSV60216116; called by muse, mutect2, varscan2
- OR8G5 | c.512T>G p.F171C | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100422200; called by muse, mutect2, varscan2
- OXR1 | c.436G>A p.E146K (on ENST00000442977 / NM_001198532.1; = p.E145K on NM_018002.3) | Missense Mutation (SNP) | VAF 159/428 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV100366616; called by muse, mutect2, varscan2
- P3H2 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as rs373927327; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH15 | c.3725T>G p.V1242G | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV100214524; called by muse, mutect2, varscan2
- PCDHA4 | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.16); catalogued as rs1360812183, COSV100793118, COSV63541646; called by muse, mutect2, varscan2
- PREX2 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.906); catalogued as rs778971988, COSV55775740; called by muse, mutect2, varscan2
- PTPRJ | c.1630T>C p.F544L | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV101394354; called by muse, mutect2, varscan2
- PTPRJ | c.2153-1G>T p.X718_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | catalogued as COSV101394359; called by muse, mutect2, varscan2
- RANGAP1 | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100663631; called by muse, mutect2, varscan2
- RNF10 | c.1814A>C p.Q605P | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV100378444; called by muse, mutect2, varscan2
- RPL10L | c.223T>A p.Y75N | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.58); catalogued as COSV100022368; called by muse, mutect2, varscan2
- RXFP3 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1478043068, COSV57507354; called by muse, mutect2, varscan2
- SALL3 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101609923; called by muse, mutect2, varscan2
- SCML2 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs376375521; called by muse, mutect2, varscan2
- SMS | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV101047899; called by muse, mutect2, varscan2
- SPIDR | c.2302G>C p.D768H | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1180825511, COSV99854124; called by muse, mutect2, varscan2
- SRBD1 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1209270160, COSV55401215, COSV55405655; called by muse, mutect2, varscan2
- TCHH | c.3554G>A p.R1185K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV100914887; called by muse, mutect2, varscan2
- TMED1 | c.382C>T p.L128F | Missense Mutation (SNP) | VAF 46/674 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.532); catalogued as rs780912898, COSV99284012; called by muse, mutect2
- TMED1 | c.381C>A p.S127R | Missense Mutation (SNP) | VAF 44/653 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV99284015; called by muse, mutect2
- TMEM132D | c.2863C>A p.Q955K | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101242532; called by muse, mutect2, varscan2
- TRABD2A | c.341T>G p.V114G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100119590; called by muse, mutect2
- TTC16 | c.2040G>C p.Q680H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV100262659; called by muse, mutect2, varscan2
- UEVLD | c.94T>C p.F32L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100260770; called by muse, mutect2, varscan2
- UTRN | c.7640C>A p.S2547Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100838009; called by muse, mutect2, varscan2
- VPS13D | c.9724C>A p.P3242T | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99165399; called by muse, mutect2, varscan2
- WDR6 | c.804G>C p.E268D | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.057); catalogued as COSV100556122, COSV100556768; called by muse, mutect2, varscan2
- XPOT | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs1468524661, COSV100225310; called by muse, mutect2, varscan2
- YIPF2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 18/365 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV53403133, COSV99449963; called by muse, mutect2
- ZNF57 | c.529T>C p.C177R | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100182720; called by muse, mutect2
- MCUB | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.162); called by muse, mutect2
- SUSD6 | c.245del p.G82Afs*6 | Frame Shift Del (DEL) | VAF 25/151 reads (17%) | called by mutect2, pindel, varscan2
- ANKS4B | c.690G>A p.V230= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100289694; called by muse, mutect2, varscan2
- ARHGAP6 | c.477C>T p.S159= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs372579291, COSV100497091; called by muse, mutect2, varscan2
- BOD1L1 | c.1878A>G p.E626= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs531586027, COSV50007580; called by muse, mutect2, varscan2
- CDRT4 | c.174C>T p.L58= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as rs757615520, COSV56466749; called by muse, mutect2, varscan2
- EPHX3 | c.906G>T p.L302= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV99691437; called by muse, mutect2, varscan2
- HARBI1 | c.624C>T p.L208= | Silent (SNP) | VAF 64/166 reads (39%) | catalogued as rs201216223, COSV100365469; called by muse, mutect2, varscan2
- LRP1B | c.8298C>T p.F2766= | Silent (SNP) | VAF 34/158 reads (22%) | catalogued as COSV101251689; called by muse, varscan2
- MADD | c.2226G>T p.V742= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100210951; called by muse, mutect2, varscan2
- MIA3 | c.5061G>A p.V1687= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100484764; called by muse, mutect2, varscan2
- MYH14 | c.3780G>T p.L1260= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99221623; called by muse, mutect2, varscan2
- NR4A1 | c.306G>A p.K102= | Silent (SNP) | VAF 46/82 reads (56%) | catalogued as COSV99670971; called by muse, mutect2, varscan2
- OR2C1 | c.189C>A p.L63= | Silent (SNP) | VAF 85/252 reads (34%) | catalogued as COSV100514826; called by muse, mutect2, varscan2
- RRP12 | c.261C>T p.L87= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs1290246831, COSV59665166, COSV59670335; called by muse, mutect2, varscan2
- SNX29 | c.1995G>C p.V665= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100027058, COSV100028958; called by muse, mutect2
- TAS2R38 | c.252G>A p.L84= | Silent (SNP) | VAF 59/187 reads (32%) | catalogued as COSV101516331, COSV71885389; called by muse, mutect2, varscan2
- TBXT | c.318C>T p.N106= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV51616182; called by muse, mutect2, varscan2
- TENT5B | c.1197G>T p.V399= | Silent (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- TMEM241 | c.390C>T p.L130= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV101271685; called by muse, mutect2, varscan2
- TPTE | c.1470C>T p.D490= (on ENST00000618007 / NM_199261.4; = p.D472= on NM_199259.4) | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- UCP1 | c.663C>T p.I221= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs1053079737, COSV53768928; called by muse, mutect2, varscan2
- ZNF646 | c.4743C>T p.D1581= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs138904435; called by muse, mutect2, varscan2
- CAV2 | c.*8G>C | 3'UTR (SNP) | VAF 27/112 reads (24%) | catalogued as COSV99760707; called by muse, mutect2, varscan2
- SSX9P | n.27G>A | RNA (SNP) | VAF 44/245 reads (18%) | catalogued as rs781850948; called by muse, mutect2, varscan2
- VAPA | c.418-5456G>C | Intron (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100486005; called by muse, mutect2, varscan2
